CCDI case PBBPEP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/44cb5b39-e18b-47c7-8771-027ac3a804a0

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 9.3 years (3,407 days).

Biospecimens (3 samples)
- Sample 0DDVSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDVSR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEK16: Tissue type: Tumor; Specimen type: Solid Tissue.
